Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A3UZ, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A3UZ-01A (Primary Tumor).

[page 1 of 3]
4/30/12

Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

Clinical Diagnosis & History:

Bilateral thyroid nodules, history left lobe PTC positive.

Specimens Submitted:

- 1: Tissue near left upper pole (fs)
- 2: Left paratracheal tissue (fs)
- 3: Total thyroidectomy

DIAGNOSIS:

1. Tissue near left upper pole, biopsy (fs):
-Benign thyroid tissue.
2. Left paratracheal tissue, excision (fs):
-One benign lymph node (0/1).

ICD-O-3

Carcinoma, papillary, thyroid
8260/3

Site: thyroid, NOS

C73.9

5-2-12
RD

3. Total thyroidectomy:

Part # 3

Tumor Type:

Five foci of papillary carcinoma: one classical type and four microcarcinomas

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Tumor Location:

Left lobe

Right lobe

The largest tumor focus is located in the right lobe

Tumor Size:

Tumor foci range from 0.4 cm to 1.1 cm in greatest dimension

Tumor Encapsulation:

Partially surrounded
for the largest tumor focus

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Invades: perithyroidal adipose tissue and parathyroid gland

[page 2 of 3]
Surgical Margins:
Free of tumor

Tumor Multicentricity:
Gross and microscopic

Non-Neoplastic Thyroid:
Exhibits nodular hyperplasia
Exhibits chronic lymphocytic thyroiditis

Parathyroid Glands:
Identified
Two parathyroid glands, one in each lobe (the right one is intrathyroidal). Tumor involves the parathyroid gland on the left side.

Lymph Nodes:
Two benign lymph nodes (0/2)

Note: The congo red stain and the immunohistochemical stains for chromogranin, synaptophysin, CEA-M, and calcitonin were performed on one of the thyroid nodules and they are negative.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	CHR	
	SYN	
	CEA M	
	CALC	
	CONGO	
	IMM RECUT	
	NEG CONT	

Gross Description:

1) The specimen is received fresh for frozen section, labeled "tissue near left upper pole," and consists of a tan pink soft tissue measuring 0.6 x 0.4 x 0.3 cm. The specimen is entirely submitted for frozen section.

Summary of sections:
FSC-frozen section control

2) The specimen is received fresh for frozen section, labeled "left paratracheal tissue," and consists of a tan soft tissue measuring 0.5 x 0.4 x 0.3 cm. The specimen is entirely submitted for frozen section.

Summary of sections:
FSC-frozen section control

3) The specimen is received fresh, labeled "total thyroidectomy, stitch marks left lobe", and consists of a thyroid weighing 22 g. The right lobe measures 4.5 x 3 x 2 cm, the left lobe measures 4.5 x 3 x 2 cm and the isthmus measures 3 x 1 x 1 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals two separate nodules measuring 0.8 cm and 0.3 cm in diameter. The nodules are located in the right lower pole, they display white/tan cut surfaces, and they are not encapsulated. Sections through the remaining tissue reveal another nodule in middle portion of left lobe measuring 0.5 cm in diameter and is not encapsulated. The remaining thyroid parenchyma is red brown

[page 3 of 3]
and beefy. Representative sections of the specimen submitted for
submitted. A small portion of right lobe nodule is submitted for

and a photograph has been taken. The entire thyroid is /

Summary of sections:

RN1 - right lobe nodule, entirely submitted

RN2—right lobe nodule (small)

RL - right lobe

LN—left lobe nodule, entirely submitted

LL - left lobe

IS - isthmus

Summary of Sections:

Part 1: Tissue near left upper pole (fs)

Block	Sect. Site	PCs
1	FSC	1

Part 2: Left paratracheal tissue (fs)

Block	Sect. Site	PCs
1	FSC	1

Part 3: Total thyroidectomy

Block	Sect. Site	PCs
4	IS	5
9	LL	10
2	LN	3
3	RL	4
2	RN1	5
2	RN2	3

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. Frozen Section Diagnosis: Tissue near left upper pole (fs): Benign thyroid tissue
Permanent Diagnosis: same
2. Frozen Section Diagnosis: Left paratracheal tissue (fs): One benign lymph node (0/1)
Permanent Diagnosis: same

Source: NCI Genomic Data Commons file 2d4f7baf-f0a2-4dbb-8885-b9deb9de1aa8 (TCGA-DJ-A3UZ.16D17ADE-B455-481E-A233-76E96DDCB635.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).